Gene-level copy-number profile of tumor specimen C3L-00963-01 from CPTAC case C3L-00963, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.7 years (21,815 days).
Specimen C3L-00963-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 398ce191-16b6-4fbc-ab0d-2d686cad8e7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00963-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/ff4e8921-53fb-4630-aff8-f00ddf318360

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 9; copy number 2: 14,431; copy number 3: 539; copy number 4: 37,096; copy number 5: 1,626; copy number 6: 2,795; copy number 7: 95; copy number 8: 963; copy number 9: 84; copy number 10: 100; copy number 11: 256; copy number 12: 209; copy number 13: 29; copy number 14: 22; copy number 15: 16; copy number 16: 58; copy number 19: 1; copy number 21: 23; copy number 23: 20; copy number 33: 13.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr8:89,412,621–89,415,071, 1 gene: KRT8P4.
- chr9:25,780,032–25,938,434, 2 genes: LINC01241, FAM71BP1.
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–4): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–4): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 831 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,698,940–47,387,601, 20 genes, copy number 9: LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP.
- chr2:53,864,069–53,970,993, 1 gene, copy number 13 (within-gene range 8–13): PSME4.
- chr2:67,562,067–68,024,766, 5 genes, copy number 9–16: LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1.
- chr2:75,710,782–75,728,123, 2 genes, copy number 9 (within-gene range 4–9): AC005034.6, AC005034.4.
- chr3:184,335,926–184,361,650, 2 genes, copy number 11 (within-gene range 6–11): FAM131A, CLCN2.
- chr4:73,571,550–73,778,060, 4 genes, copy number 9: RASSF6, UMLILO, CXCL8, AC112518.1.
- chr6:11,093,834–11,515,710, 8 genes, copy number 9 (within-gene range 7–9): SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1.
- chr8:37,326,575–42,139,752, 117 genes, copy number 12 (broad region; genes not listed).
- chr8:60,289,928–63,234,911, 43 genes, copy number 9–11: LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:67,952,046–68,331,689, 6 genes, copy number 9 (within-gene range 4–9): PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1.
- chr8:80,484,561–81,112,068, 19 genes, copy number 11–12: AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2.
- chr8:109,086,585–137,698,467, 320 genes, copy number 11–23 (broad region; genes not listed).
- chr11:12,303,533–15,622,447, 51 genes, copy number 15–33: AC025300.1, PARVA, AC009806.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1.
- chr11:24,455,911–25,141,023, 4 genes, copy number 10–13: Y_RNA, LUZP2, AC115990.1, AC087373.1.
- chr12:47,463,087–48,106,079, 31 genes, copy number 9 (within-gene range 4–9): ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1.
- chr17:37,514,807–39,977,768, 99 genes, copy number 10–21 (broad region; genes not listed).
- chr17:41,754,604–41,786,931, 1 gene, copy number 9: JUP.
- chr17:63,622,415–64,919,480, 64 genes, copy number 10 (broad region; genes not listed).
- chr20:63,843,436–64,327,972, 34 genes, copy number 10: C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
